Gene-level copy-number profile of tumor specimen C3L-03748-04 from CPTAC case C3L-03748, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.0 years (23,735 days).
Specimen C3L-03748-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 986e1ed0-d732-4ceb-a456-c3df820d66cd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03748-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/ac61ad41-fb38-4566-804d-6c6d8a01f9b4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 136; copy number 1: 1; copy number 2: 3,101; copy number 3: 1,306; copy number 4: 47,816; copy number 5: 3,004; copy number 6: 2,861; copy number 9: 1; copy number 15: 3; copy number 17: 108; copy number 19: 41; copy number 20: 8; copy number 173: 16.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:6,704,270–6,707,780, 1 gene: LINC02851.
- chr9:21,058,771–26,118,408, 75 genes (broad region; genes not listed).
- chr10:87,504,875–89,701,274, 57 genes: MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4.
- chr10:91,409,280–91,545,098, 3 genes: HECTD2, AL161798.1, RPS27P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 177 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:52,252,820–62,220,470, 141 genes, copy number 17–19 (broad region; genes not listed).
- chr5:1,252,006–1,445,440, 8 genes, copy number 20: AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3.
- chr5:2,921,496–2,967,955, 1 gene, copy number 17: AC094105.2.
- chr5:6,448,859–6,600,288, 3 genes, copy number 15 (within-gene range 2–15): UBE2QL1, AC027334.1, LINC01018.
- chr5:8,157,541–8,157,788, 1 gene, copy number 9: AC091912.1.
- chr5:8,669,018–8,898,052, 7 genes, copy number 17: AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199.
- chr7:54,419,444–55,433,742, 16 genes, copy number 173: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
